Surgical pathology report (de-identified scan), TCGA case TCGA-DS-A0VM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-DS-A0VM-01A (Primary Tumor).

[page 1 of 5]
Squamous cell carcinoma, NOS

8076/3

Site: Cervix, NOS

C53.9

12/7/10

lw

Attending MD:

Ordering MD:

Copies To:

DIAGNOSIS:

1. FALLOPIAN TUBE AND OVARY, RIGHT, SALPINGO-OOPHORECTOMY:
- Ovary with a follicular cyst, serosal adhesion, and mild hyperplasia of rete elements
- Fallopian tube with minimal chronic inflammation and aggregates of inflammatory cells (mostly histiocytes/macrophages) in lumen
- Paratubal cystic Walthard rests
- No evidence of metastatic carcinoma
2. FALLOPIAN TUBE AND OVARY, LEFT, SALPINGO-OOPHORECTOMY:
- Ovary with serosal adhesions
- Fallopian tube with minimal chronic inflammation, accumulations of inflammatory cells (mostly histiocytes/macrophages) in lumen, and focal epithelial hyperplasia associated mild atypia
- Several paratubal cystic Walthard rests
- No evidence of metastatic carcinoma
3. LYMPH NODES, RIGHT PELVIC, EXCISION:
- Four reactive lymph nodes with sinus histiocytosis, fibrosis, and/or partial replacement by benign adipose tissue
- No evidence of metastatic carcinoma (0/4) [see comment]
4. LYMPH NODE, RIGHT PERIAORTIC, EXCISION:
- One reactive lymph node with sinus histiocytosis, foci of fibrosis, and partial replacement by benign adipose tissue
- No evidence of metastatic carcinoma (0/1)
5. LYMPH NODES, LEFT PELVIC, EXCISION:
- Two of four lymph nodes positive for metastatic carcinoma (2/4) [see comment]
- Lymph nodes also show sinus histiocytosis, foci of fibrosis, and/or partial replacement by benign adipose tissue

(continued on next page)□

Department of Pathology & Laboratory Medicine

Page: 2

6. LYMPH NODES, LEFT OBTURATOR, EXCISION:
- Five reactive lymph nodes with sinus histiocytosis, foci of fibrosis, and/or partial replacement by benign adipose tissue
- No evidence of metastatic carcinoma (0/5)
7. LYMPH NODES, LEFT PERIAORTIC, EXCISION:
- Four reactive lymph nodes with sinus histiocytosis, foci of fibrosis, and/or partial replacement by benign adipose tissue
- No evidence of metastatic carcinoma (0/4)
8. LYMPH NODES, RIGHT PERIAORTIC, EXCISION:
- Two lymph nodes with partial replacement by benign adipose

[page 2 of 5]
- tissue, and/or foci of fibrosis
- No evidence of metastatic carcinoma (0/2)

9. LYMPH NODE, LEFT COMMON ILIAC, EXCISION:

- One reactive lymph node with sinus histiocytosis, foci of fibrosis, and partial replacement by benign adipose tissue
- No evidence of metastatic carcinoma (0/1)

10. UTERUS, RADICAL HYSTERECTOMY:

- Primary invasive cervical carcinoma, poorly differentiated, with predominantly squamous cell features, and associated squamous cell carcinoma in-situ (SCIS) [see comment]
- Grossly evident tumor involved the entire circumference of the cervix, measured about 3.5 cm in diameter and 3.9 cm in length
- Invasive carcinoma involves a maximum of about 80% of the cervical wall thickness
- Tumor extends into the lower uterine segment
- Lymphatic and blood vessel invasion by carcinoma is present in the cervix
- Lymphatic invasion by tumor is also present in the left parametrium
- No direct extension of carcinoma (other than that in lymphovascular spaces) into parametrial soft tissues
- One of four parametrial lymph nodes is positive for metastatic carcinoma; the affected lymph nodes is on the left side (see comment)
- Vaginal cuff, including surgical margin of vaginal cuff, is free of carcinoma
- No extension of carcinoma into the uterine corpus
- Fibrosing stromal reaction to invasive carcinoma is present
- Surface of tumor is partially ulcerated and necrotic
- Acute and chronic inflammatory reaction to tumor is present, but not exuberant
- Other findings include:
- Two uterine leiomyomas, largest of which shows areas of healed infarction with associated hyalinization, foci of edema, and small foci of cystic degeneration
- Benign inactive (atrophic to weakly proliferative) endometrium with a few cystically dilated glands and foci of ciliated epithelial metaplasia
- Mullerianosis (endometriosis/endosalpingiosis) outer uterine/lower segment wall
- Few cervical squamous cells showing atypia suggestive of human papilloma virus infection
- Changes consistent with prior cervical biopsy

(continued on next page)□

Department of Pathology & Laboratory Medicine

Page: 3

- Acute and chronic cervicitis, squamous metaplasia, parakeratosis, and endocervical nabothian cysts
- Vaginal cuff mucosa with mild chronic and minimal acute inflammation

COMMENT: The invasive carcinoma exhibits predominantly features of non-keratinizing squamous cell carcinoma. A few of the nests of tumor cells have lumen-like spaces (? true lumens versus artifacts related to tumor cell necrosis). No mucicarminophilic mucin is detected in the neoplastic cells and only very rare tumor cells contain PAS-positive, diastase-resistant mucin and/or Alcian blue PAS-positive material. Sections of the parametrial and right and left pelvic lymph nodes were stained for keratin using AE1/AE3 antibody. The metastatic tumor cells are highlighted in the affected lymph nodes, including a few "occult" metastatic tumor cells in subcapsular sinus of the affected left parametrial lymph node.

HISTORY: Cervical carcinoma
MICROSCOPIC:

[page 3 of 5]
See Diagnosis.

GROSS:

1: RIGHT ADNEXA

Labeled "right adnexa" and received in formalin is an 11.5 gram salpingo-oophorectomy specimen. The ovary is 3.4 x 1.5 x 0.7 cm and has a tan, slightly lobulated serosal surface. Cut surfaces of the ovary are grossly unremarkable. The fallopian tube has fimbria at one end, is 4.5 cm long, ranges from 0.6 to 1 cm in diameter, and has a tan-red smooth serosal surface. Attached to the fallopian tube are two thin-walled translucent fluid-filled cysts measuring 0.1 to 0.2 cm in diameter. Cross sections of the fallopian tube reveal a 0.2 to 0.4 cm diameter patent lumen. Representative sections are submitted.

A. Ovary and fallopian tube - 4

2: LEFT ADNEXA

Labeled "left adnexa" and received in formalin is an 11 gram salpingo-oophorectomy specimen. The ovary is 2.7 x 1.5 x 0.7 cm and has a tan, slightly lobulated serosal surface. Cut surfaces of the ovary are grossly unremarkable. The fallopian tube has fimbria at one end, is 4 cm long and ranges from 0.6 to 0.8 cm in diameter and has a tan-pink smooth serosal surface, except for several tiny thin-walled translucent fluid-filled paratubal cysts, ranging from about 0.1 to 0.2 cm in diameter. Cross section of the fallopian tube reveals a 0.1 to 0.2 cm diameter patent lumen. Representative sections are submitted.

B. Ovary and fallopian tube - 4

3: RIGHT PELVIC NODE

Labeled "right pelvic lymph node" and received in formalin is an aggregate of soft yellow lobulated, focally hemorrhagic fatty tissue measuring 5 x 4.5 x 1 cm. Sectioning reveals four soft tan lymph

(Continued on next page)□

Department of Pathology & Laboratory Medicine

Page: 4

nodes ranging from 0.7 to 1.2 cm. The lymph nodes are entirely submitted.

C. Four lymph nodes - 4

4: RIGHT PERIAORTIC NODE

Labeled "right periaortic node" and received in formalin is an aggregate of soft yellow lobulated fatty tissue measuring 3.5 x 3 x 0.7 cm. Sectioning reveals one soft tan lymph node measuring 2.3 cm in greatest dimension. The lymph node is entirely submitted.

D. One lymph node, sectioned - 4

5: LEFT PELVIC NODE

Labeled "left pelvic node" and received in formalin is an aggregate of soft yellow lobulated, focally hemorrhagic fatty tissue measuring 6 x 3.5 x 1 cm. Sectioning of the specimen reveals four soft tan to tan-yellow lymph nodes ranging from 1.2 to 1.8 cm. The lymph nodes are entirely submitted.

E. Two bisected lymph nodes - 4

F. Two bisected lymph nodes - 4

6: OBTURATOR NODE LEFT

Labeled "obturator node, left" and received in formalin is an aggregate of soft yellow lobulated fatty tissue measuring 2.4 x 2 x 0.3 cm. Within the fat, there are several semi-soft tan lymph nodes ranging from about 0.3 to 1.3 cm in maximum dimension. The entire specimen is submitted.

G. Multiple lymph nodes and fat - multiple

7: LEFT PA NODE

Labeled "left PA node" and received in formalin is a 2 x 1 x 0.3 cm portion of soft yellow fatty tissue, within which there are several

[page 4 of 5]
soft tan lymph nodes ranging from about 0.2 to 0.8 cm in maximum dimension. The entire specimen is submitted.

H. Fat and several lymph nodes - 1

8: RIGHT PA NODE

Labeled "right PA node" and received in formalin is a 1.4 x 1.2 x 0.3 cm fragment of soft yellow fatty tissue, within which there are two semi-soft tan-yellow lymph nodes measuring about 0.4 and 0.6 cm in maximum dimension. The entire specimen is submitted.

I. Two lymph nodes and fat - 1

9: LEFT COMMON ILIAC NODE

Labeled "left common iliac node" and received in formalin is a soft tan-yellow portion of fibromembranous tissue measuring 1.7 x 1 x 0.5 cm. Sectioning reveals one soft tan-pink, grossly unremarkable lymph node measuring 1 cm in greatest dimension. The entire specimen is submitted.

J. One lymph node and fat - 2

10: UTERUS AND CERVIX

Labeled "uterus and cervix", received fresh in the Operating Room and subsequently fixed in formalin, is a 250 gram total hysterectomy specimen. The uterus is symmetric, measuring 11 cm from fundus to ectocervix, 9 cm from cornu to cornu, and up to 5 cm from the anterior surface to the posterior surface. The uterine serosa is (continued on next page)□

Department of Pathology & Laboratory Medicine

Page: 5

tan-red and smooth. The cervix is about 3.5 cm long and has a maximum diameter of 2.5 to 3 cm in the ectocervical region. Attached to the ectocervix there is a vaginal cuff which ranges from 1.5 cm on the right posterior side to 2.7 cm on the left anterior side. The vaginal mucosa is tan, smooth and grossly free of tumor. The vaginal cuff margin is inked for orientation purposes. The ectocervix is entirely replaced by a firm, tan, ulcerated mass. The external cervical os is 1 cm in diameter and very irregular but patent. The parametrial margins are inked black and blue. The uterus is incised on both sides. The endocervical canal is completely occupied by tan firm tumor with an ulcerated surface. The tumor occupies the entire circumference of the cervix. It measures 3.9 cm in length from the ectocervix to lower uterine segment and up to 3.5 cm in maximum diameter. It is located approximately 0.2 cm from the posterior and right lateral resection margins and is at least 1 cm from the left anterior and all vaginal resection margins. The endometrial cavity is 4.5 cm long and up to 4 cm in width. The endometrial lining is tan and smooth and measures up to 0.2 cm in thickness and grossly is not involved by tumor. Within the uterus are two well-circumscribed leiomyomas that are intramural and measure 2 and 3.5 cm in maximum dimension. Both leiomyomas have a firm solid tan-white cut surface with a whorled configuration without grossly evident hemorrhage or areas of necrosis. The uninvolved muscular uterine wall has a maximum thickness of 2.3 cm. Representative sections are submitted.

K. Right parametrial tissues - 2

L. Right parametrial tissues - 1

M. Left parametrial tissues - 1

N. Right posterior cervix and adjacent vaginal cuff to margin - 1

O. Right posterior cervix and endocervix - 1

P. Left posterior ectocervix and adjacent vaginal cuff to margin - 1

Q. Left posterior ectocervix and endocervix - 1

R. Right anterior ectocervix and vaginal cuff to margin - 1

S. Mid anterior ectocervix and adjacent vaginal cuff to margin - 1

T. Left anterior cervix and adjacent vaginal cuff to margin - 1

U. Left anterior cervix and lower uterine segment

V. Left anterior endocervix and lower uterine segment - 1

W. Right anterior cervix - 1

[page 5 of 5]
X. Right anterior endocervix and lower uterine segment - 1
Y. Right posterior cervix and vaginal cuff to margin - 1
Z. Right posterior endocervix and lower uterine segment - 1
AA. Anterior lower uterine segment - 1
BB. Anterior uterine corpus - 1
CC. Posterior uterine corpus - 1
DD. Smaller leiomyoma - 1
EE. Larger leiomyoma - 1

Additional representative sections (submitted on

FF. Cervix with deeply invasive tumor - 1
GG. Cervix with deeply invasive tumor - 1

Gross dictated by M.D.

Special Studies: Additional H&Es (Mx1, Qx1, Ux1, Yx1);
(continued on next page)

Department of Pathology & Laboratory Medicine

Page: 6

keratin (C,E,F,K,M); mucicarmine (Qx2);
PAS-D (Q); Alcian blue-PAS (Q)

See Also:

.D.
Pathologist

I, M.D., the pathologist of record, have
personally examined the specimen, interpreted the
results, reviewed this report and signed it electronically.

Date Finalled:

Source: NCI Genomic Data Commons file 2cf1068f-3c47-432a-b2b5-2961c7863b20 (TCGA-DS-A0VM.7C9830C1-15CB-4D38-8995-3A061E80741F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).